Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7676, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7676-01A (Primary Tumor).

Microscopic

Microscopic examination reveals an oligodendroglioma characterized by a proliferation of neoplastic cells with round to oval nuclei and prominent perinuclear halos. Overall, the tumor appears moderately cellular. The neoplastic cells demonstrate moderate nuclear atypia. A rare cell demonstrates more marked atypical features characterized by enlarged hyperchromatic folded or clefted nuclei. Microgemistocytes are scattered throughout the tumor. The background neuropil demonstrates focal areas of microcystic change, as well as acute hemorrhage. Only one mitotic figure per 10 high power fields is counted. No necrosis or microvascular proliferation is identified. Overall, these histologic features are consistent with an oligodendroglioma.

Addendum

The MIB-1 labeling index ranges up to 2.1% consistent with a low grade neoplasm.

Diagnosis

Oligodendroglioma grade II

Source: NCI Genomic Data Commons file 1a219a11-3da0-4957-a9e4-0667d01b5b65 (TCGA-HT-7676.275566DC-510F-46F1-8E3D-7141885F4754.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).